Somatic mutation profile of tumor specimen TCGA-KP-A3W3-01A (aliquot TCGA-KP-A3W3-01A-11D-A228-09) from TCGA case TCGA-KP-A3W3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.0 years (26,310 days).
Specimen TCGA-KP-A3W3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7646fda4-e045-4857-a434-c81e26358b81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KP-A3W3-10A (Blood Derived Normal), aliquot TCGA-KP-A3W3-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8287c4a8-7251-4964-9eb8-ef6836d01a22

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Frame Shift Del 1, Nonsense Mutation 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAX3 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553593928, CM004276, CM155604, COSV99286375, COSV99286403; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 39/75 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 59/76 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMY2B | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100796174; called by muse, mutect2, varscan2
- ANK2 | c.4087A>G p.N1363D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99999590; called by muse, mutect2, varscan2
- ARHGAP35 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101350692; called by muse, mutect2, varscan2
- CAMTA1 | c.2699A>G p.N900S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756848658, COSV100346156; called by muse, mutect2, varscan2
- CRTC2 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100338821; called by muse, mutect2, varscan2
- E2F5 | c.698C>G p.S233W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1359761480, COSV99809282; called by muse, mutect2, varscan2
- EFHC2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs372128695, COSV101375435; called by muse, mutect2, varscan2
- FBN3 | c.7158C>G p.F2386L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99559698; called by muse, mutect2, varscan2
- GREB1 | c.1294A>T p.I432F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as COSV99302195; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99646850; called by muse, mutect2, varscan2
- IL2RG | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs374102717, COSV52147830; called by muse, mutect2, varscan2
- MACF1 | c.16159C>A p.Q5387K (on ENST00000372915; = p.Q3320K on NM_012090.5) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV99241084; called by muse, mutect2, varscan2
- MDN1 | c.14632G>C p.A4878P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV101020744; called by muse, mutect2
- MYOC | c.958A>G p.R320G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV99231293; called by muse, mutect2, varscan2
- PCCA | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs766876474, COSV100886510; called by muse, mutect2, varscan2
- RAI1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs774552382, COSV55391566; called by muse, mutect2, varscan2
- RIOK2 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV99299750; called by muse, mutect2, varscan2
- STK36 | c.2489A>G p.H830R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV99830995; called by muse, mutect2, varscan2
- TSHZ3 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs766793830, COSV53669970; called by muse, mutect2, varscan2
- ZNF799 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs752438094, COSV101345234, COSV70123430; called by muse, mutect2, varscan2
- TFDP2 | c.1141_1147del p.T381Pfs*5 (on ENST00000489671 / NM_001178139.2; = p.T321Pfs*5 on NM_006286.5) | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- ARRDC1 | c.1074C>T p.P358= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100603476; called by muse, mutect2, varscan2
- CACNA1S | c.2835C>T p.I945= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs753072795, COSV100754637; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CDH7 | c.2079G>A p.L693= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1158451939, COSV100541398; called by muse, mutect2, varscan2
- CFAP61 | c.1821C>A p.S607= | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as COSV99843198; called by muse, mutect2, varscan2
- GPR180 | c.351G>A p.P117= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs560801980, COSV65385591; called by muse, mutect2, varscan2
- IFNB1 | c.204G>A p.L68= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs771382672, COSV101207774; called by muse, mutect2, varscan2
- MAP3K9 | c.936G>A p.T312= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs976450856, COSV101173447; called by muse, mutect2, varscan2
- NELL1 | c.288G>A p.K96= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100118814; called by muse, mutect2, varscan2
- PLXNB1 | c.6393G>A p.K2131= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99602217; called by muse, mutect2, varscan2
- PSAP | c.126C>T p.C42= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs372943091; called by muse, mutect2, varscan2
- SAMD11 | c.564G>T p.P188= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100497821, COSV100498124; called by muse, mutect2, varscan2
- TEC | c.1575T>G p.A525= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99972157; called by muse, mutect2, varscan2
- TENT5C | c.174G>T p.R58= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV101032760; called by muse, mutect2
- Unknown | chr21:16071325 A>C | IGR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
